Somatic mutation profile of tumor specimen TCGA-EE-A29X-06A (aliquot TCGA-EE-A29X-06A-11D-A196-08) from TCGA case TCGA-EE-A29X, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.3 years (21,662 days).
Specimen TCGA-EE-A29X-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) add0c9af-6dc5-4e66-a244-906f9633a83e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A29X-10A (Blood Derived Normal), aliquot TCGA-EE-A29X-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbb74c1b-32af-499c-99d3-948770f29c00

The open-access MAF lists 175 somatic variants for this specimen: 108 protein-altering or splice-affecting, 65 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 65, Splice Site 3, Nonsense Mutation 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO18B | c.3052C>T p.P1018S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.67); PolyPhen benign (0.344); catalogued as COSV100123667, COSV59127388; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 147/247 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RMND1 | c.504+1G>A p.X168_splice | Splice Site (SNP) | VAF 15/29 reads (52%) | catalogued as rs1562800908, CS128794, COSV60550482; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 16/22 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS12 | c.3559G>A p.A1187T | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs780835542, COSV61261776, COSV61262030; called by mutect2, varscan2
- AKAP1 | c.981T>G p.N327K | Missense Mutation (SNP) | VAF 69/129 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV58470022; called by muse, mutect2, varscan2
- ANKRD50 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1476247796, COSV72385476; called by mutect2, varscan2
- ANKS1A | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs767459384, COSV64460318; called by muse, mutect2, varscan2
- ARHGAP36 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52266328; called by mutect2, varscan2
- ARHGAP36 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.992); catalogued as COSV52266343; called by muse, varscan2
- ARPC3 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV57400694; called by muse, mutect2, varscan2
- ARPC3 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV57399458; called by muse, mutect2, varscan2
- ATXN7L3 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV66988916; called by muse, mutect2, varscan2
- BIRC2 | c.1565A>G p.N522S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV57161227; called by muse, mutect2, varscan2
- BRAT1 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1470142306, COSV61395154; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C16orf71 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV73918491; called by muse, mutect2, varscan2
- CACNA1D | c.3622G>A p.E1208K (on ENST00000350061 / NM_001128840.3; = p.E1228K on NM_000720.4) | Missense Mutation (SNP) | VAF 109/289 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55445291; called by muse, mutect2, varscan2
- CALB2 | c.130T>G p.F44V | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56939129; called by muse, mutect2
- CAPN3 | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1555420495, CM070050, COSV58821671; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPN6 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.142); catalogued as rs757232908, COSV60694793; called by muse, mutect2, varscan2
- CASS4 | c.353G>A p.S118N | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as rs759957814, COSV64386267; called by muse, mutect2, varscan2
- CCDC141 | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 103/318 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55372834; called by mutect2, varscan2
- CCDC30 | c.637G>A p.E213K (on ENST00000340612; = p.E170K on NM_001080850.3) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as COSV59606220; called by muse, mutect2, varscan2
- CDC42EP1 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.186); catalogued as COSV50756390; called by muse, mutect2, varscan2
- CDH10 | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV52573710; called by muse, mutect2, varscan2
- CHMP4B | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV54135109; called by muse, mutect2, varscan2
- COL14A1 | c.3824G>A p.R1275K | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99918866; called by muse, mutect2, varscan2
- COL14A1 | c.3824+1G>A p.X1275_splice | Splice Site (SNP) | VAF 32/85 reads (38%) | catalogued as COSV99918867; called by muse, mutect2, varscan2
- CORIN | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV56690707; called by muse, varscan2
- CRB1 | c.2129-1G>A p.X710_splice | Splice Site (SNP) | VAF 14/82 reads (17%) | catalogued as COSV66329889, COSV66331406; called by muse, mutect2, varscan2
- CXCL14 | c.119C>T p.S40F (on ENST00000337225; = p.S28F on NM_004887.5) | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV61499221; called by muse, mutect2, varscan2
- CYP3A5 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV56118453, COSV99769387; called by muse, varscan2
- DNAH5 | c.10495G>A p.E3499K | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs148592658, COSV54221637; called by mutect2, varscan2
- DNAJC5 | c.136A>T p.K46* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV62671502; called by muse, mutect2, varscan2
- EDN3 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs774307682, CM972863, COSV61107812; called by mutect2, varscan2
- ERBB4 | c.2720G>A p.G907E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61483799, COSV61498093; called by muse, mutect2
- ERC1 | c.2738G>C p.R913P (on ENST00000360905 / NM_178040.4; = p.R885P on NM_178039.4) | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61694407; called by muse, mutect2, varscan2
- ETV6 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 63/273 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs1466031507, COSV67149688, COSV67151783; called by muse, mutect2, varscan2
- EXPH5 | c.4445G>A p.R1482K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV99761421; called by muse, mutect2, varscan2
- FAM149A | c.2240T>A p.I747N (on ENST00000356371 / NM_001367768.2; = p.I456N on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV57027155; called by muse, mutect2, varscan2
- FAM227B | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.039); catalogued as rs184983763, COSV54815876; called by mutect2, varscan2
- FANCD2 | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.014); catalogued as rs1231761206, COSV55033207; called by mutect2, varscan2
- FBXO36 | c.527G>A p.R176K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99391556; called by muse, mutect2, varscan2
- GCSAML | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867795960, COSV63577305; called by muse, mutect2, varscan2
- GSTCD | c.1894C>G p.P632A (on ENST00000360505 / NM_001031720.3; = p.P545A on NM_024751.3) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64733209; called by muse, mutect2, varscan2
- IGF2BP1 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51730981; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779327718; called by muse, mutect2, varscan2
- ITGB4 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52325224; called by muse, mutect2, varscan2
- KDR | c.3299C>T p.S1100F | Missense Mutation (SNP) | VAF 64/201 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868047715, COSV55764136; called by muse, mutect2, varscan2
- KIF4A | c.1747C>T p.Q583* | Nonsense Mutation (SNP) | VAF 34/109 reads (31%) | catalogued as COSV65542922; called by mutect2, varscan2
- KLHL35 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV66219309; called by muse, mutect2
- LRP1B | c.7262C>T p.S2421L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs770900012, COSV67213157; called by muse, varscan2
- LRRK1 | c.1939C>T p.P647S | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV52609830; called by muse, mutect2, varscan2
- MAGEB6 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as rs1308782720, COSV66872202; called by muse, mutect2, varscan2
- MSR1 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs376521402, COSV50510831; called by muse, mutect2, varscan2
- NELL2 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV100419898, COSV61573858; called by muse, mutect2
- NOTCH4 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 152/405 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV66680473; called by muse, mutect2, varscan2
- NOX1 | c.136C>T p.L46F | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs757688304, COSV54194326; called by muse, mutect2, varscan2
- OR10J1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV71128713; called by mutect2, varscan2
- OR13G1 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV62943694, COSV62944053, COSV62944093; called by muse, mutect2, varscan2
- OR14C36 | c.13A>G p.T5A | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV58601149; called by muse, mutect2, varscan2
- OR2M2 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV62898059, COSV62899018; called by muse, mutect2, varscan2
- OSBPL6 | c.2420C>T p.P807L | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV99507219; called by muse, mutect2, varscan2
- OTOA | c.1883C>T p.S628F (on ENST00000286149; = p.S614F on NM_144672.4) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs868666952, COSV53753266; called by muse, mutect2, varscan2
- PADI3 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs201243010; called by muse, mutect2
- PCCB | c.913A>G p.I305V | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs538202253, COSV52444909; called by muse, varscan2
- PCDHB5 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV50650539; called by muse, mutect2, varscan2
- PCLO | c.8095C>T p.P2699S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs551639501, COSV100437801, COSV61624916; called by muse, mutect2, varscan2
- PCLO | c.5443C>T p.R1815* | Nonsense Mutation (SNP) | VAF 72/182 reads (40%) | catalogued as COSV61632275; called by mutect2, varscan2
- PHLDB2 | c.2450G>A p.G817E (on ENST00000393925 / NM_001134439.2; = p.G774E on NM_145753.2) | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV67310768; called by muse, mutect2, varscan2
- PLK2 | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.323); catalogued as COSV57107043; called by muse, mutect2, varscan2
- PLXNB1 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.262); catalogued as COSV56489306, COSV56492410; called by muse, mutect2, varscan2
- PRAMEF14 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 66/101 reads (65%) | SIFT tolerated (0.37); PolyPhen benign (0.156); catalogued as rs1247941997; called by muse, mutect2, varscan2
- PTPRR | c.86T>G p.F29C | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); catalogued as COSV51730903; called by muse, mutect2, varscan2
- PXK | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1380084100, COSV57088722; called by muse, mutect2, varscan2
- RELN | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58999647; called by muse, varscan2
- RPS6KA6 | c.779G>C p.G260A | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV53119261; called by muse, mutect2, varscan2
- RSBN1 | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 64/104 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54731075; called by mutect2, varscan2
- SCN4A | c.1040A>G p.N347S | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.491); catalogued as rs367545756; called by muse, mutect2, varscan2
- SDC2 | c.464T>C p.I155T | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs771639024, COSV56227299; called by muse, varscan2
- SGCG | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs1251453924, COSV54559622; called by muse, mutect2, varscan2
- SLC9A1 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1309855858, COSV56053097; called by muse, mutect2, varscan2
- SLIT2 | c.3176G>A p.G1059E | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV56570339; called by muse, varscan2
- SLITRK2 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59425040; called by muse, mutect2, varscan2
- SPAG16 | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs747422881, COSV56969736; called by muse, mutect2, varscan2
- SPNS2 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61231717; called by muse, mutect2, varscan2
- SPON1 | c.2135G>A p.R712Q | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.985); catalogued as rs148033537, COSV59960524; called by mutect2, varscan2
- STK31 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63453951; called by muse, mutect2, varscan2
- STPG2 | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54795106; called by muse, mutect2, varscan2
- TEC | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV67403538; called by muse, mutect2, varscan2
- TIE1 | c.2638G>A p.D880N | Missense Mutation (SNP) | VAF 86/320 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV65249558; called by mutect2, varscan2
- TLE3 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs1283746377, COSV58168850; called by muse, mutect2, varscan2
- TLN1 | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs774077967, COSV59206553; called by mutect2, varscan2
- TNFAIP8L3 | c.487C>T p.H163Y | Missense Mutation (SNP) | VAF 91/273 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59528550; called by muse, mutect2, varscan2
- TPTE | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1255945263; called by mutect2, varscan2
- TRANK1 | c.6976G>A p.D2326N | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs770012167, COSV57148755; called by muse, mutect2, varscan2
- TRIM29 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.175); catalogued as COSV59280138; called by muse, mutect2, varscan2
- TRIM36 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.313); catalogued as COSV56690032; called by muse, varscan2
- TRIOBP | c.6176G>A p.G2059E (on ENST00000644935 / NM_001039141.3; = p.G346E on NM_007032.5) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV58525832, COSV58526146; called by muse, mutect2, varscan2
- TRPC6 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as rs267602664, CM156589, CM158444, COSV60251176; called by muse, mutect2, varscan2
- TRPV5 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs755955591, COSV54685377; called by muse, mutect2, varscan2
- TYSND1 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV54642864; called by muse, mutect2, varscan2
- UGT2B28 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as rs761339587, COSV59430554; called by muse, mutect2, varscan2
- VSTM2A | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV56493514; called by muse, mutect2
- WDR75 | c.2051T>A p.L684Q | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59105460; called by muse, mutect2, varscan2
- WDR82 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV56601645; called by mutect2, varscan2
- ZFP36L1 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 80/136 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV60544537, COSV60545284; called by mutect2, varscan2
- ZNF81 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100095561; called by muse, mutect2, varscan2
- ABCA13 | c.14007C>T p.L4669= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV68946229; called by muse, mutect2, varscan2
- ADAMTS18 | c.3228G>A p.E1076= | Silent (SNP) | VAF 92/166 reads (55%) | catalogued as COSV51407217; called by muse, mutect2, varscan2
- ARMC12 | c.592C>T p.L198= (on ENST00000373866 / NM_001286574.2; = p.L225= on NM_145028.5) | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as COSV55360089; called by muse, mutect2, varscan2
- CAMK4 | c.1299G>A p.E433= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV56669899; called by muse, mutect2, varscan2
- CBY2 | c.573G>A p.K191= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as rs371332004; called by muse, mutect2, varscan2
- CCDC138 | c.1710C>T p.F570= | Silent (SNP) | VAF 48/185 reads (26%) | catalogued as rs754543103, COSV54566701; called by muse, mutect2, varscan2
- CCR3 | c.189G>A p.R63= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV100656324, COSV62463131; called by muse, mutect2, varscan2
- CDH10 | c.1845C>T p.I615= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as rs756815430, COSV52574073; called by mutect2, varscan2
- CHMP4B | c.336C>T p.A112= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs777388581, COSV54136632; called by mutect2, varscan2
- CNGB3 | c.726C>T p.F242= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV60688986; called by muse, varscan2
- CNTN5 | c.897G>A p.E299= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV54307086; called by muse, mutect2, varscan2
- COL6A3 | c.4071G>A p.V1357= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV55088037; called by muse, mutect2, varscan2
- CYP11A1 | c.765C>T p.F255= | Silent (SNP) | VAF 46/158 reads (29%) | catalogued as COSV51431839; called by muse, varscan2
- CYP4B1 | c.765C>T p.D255= | Silent (SNP) | VAF 22/158 reads (14%) | catalogued as COSV54723273; called by muse, varscan2
- DGKB | c.1642C>T p.L548= | Silent (SNP) | VAF 63/167 reads (38%) | catalogued as COSV51779603; called by muse, mutect2, varscan2
- EGFLAM | c.987G>A p.Q329= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs767984778, COSV100379951, COSV59300726; called by muse, mutect2, varscan2
- ELMOD1 | c.177G>A p.R59= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV56192362; called by muse, mutect2, varscan2
- ENPP3 | c.1185C>T p.F395= | Silent (SNP) | VAF 108/193 reads (56%) | catalogued as COSV62954068, COSV62954093; called by muse, mutect2, varscan2
- EXPH5 | c.4446G>A p.R1482= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99761417; called by muse, mutect2, varscan2
- FAT3 | c.3579G>A p.Q1193= | Silent (SNP) | VAF 117/333 reads (35%) | catalogued as COSV53105082; called by muse, mutect2, varscan2
- FLNB | c.1179G>A p.V393= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV55878411; called by muse, varscan2
- GLUD2 | c.1137G>A p.L379= | Silent (SNP) | VAF 86/241 reads (36%) | catalogued as COSV60151843; called by muse, mutect2, varscan2
- GRIN2B | c.1293G>A p.R431= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV74205754, COSV74206520; called by muse, mutect2, varscan2
- GSTCD | c.1611C>T p.C537= (on ENST00000360505 / NM_001031720.3; = p.C450= on NM_024751.3) | Silent (SNP) | VAF 48/126 reads (38%) | catalogued as rs200562242, COSV64733198; called by muse, mutect2, varscan2
- IGHV3-73 | c.109C>T p.L37= | Silent (SNP) | VAF 38/66 reads (58%) | called by muse, mutect2, varscan2
- IL1RAPL2 | c.153G>A p.V51= | Silent (SNP) | VAF 40/116 reads (34%) | catalogued as rs782591779, COSV61155214; called by mutect2, varscan2
- IL2RB | c.822G>A p.L274= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV53426108; called by mutect2, varscan2
- IL37 | c.405G>A p.L135= | Silent (SNP) | VAF 52/111 reads (47%) | catalogued as COSV54490894; called by muse, mutect2, varscan2
- IVL | c.1575G>A p.Q525= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV64216151; called by muse, mutect2
- JADE3 | c.1998C>T p.S666= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs781914769, COSV54466172; called by muse, mutect2
- KLK5 | c.600C>T p.F200= | Silent (SNP) | VAF 42/61 reads (69%) | catalogued as COSV60450220; called by muse, mutect2, varscan2
- KMT2A | c.7674A>G p.P2558= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as COSV63285345; called by muse, mutect2, varscan2
- KRT36 | c.1200G>A p.E400= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs1292438332, COSV60203241; called by muse, mutect2, varscan2
- MAP1A | c.5571C>T p.L1857= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV55808236; called by muse, mutect2, varscan2
- MRPS15 | c.306G>A p.E102= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV100910638, COSV64152197; called by muse, mutect2, varscan2
- MUC16 | c.37959G>A p.R12653= | Silent (SNP) | VAF 68/164 reads (41%) | catalogued as rs754362250, COSV67462713; called by muse, mutect2, varscan2
- NAALADL1 | c.66C>T p.I22= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV60523811; called by muse, mutect2, varscan2
- NCAPD2 | c.2988C>T p.I996= | Silent (SNP) | VAF 74/253 reads (29%) | catalogued as rs765761412, COSV59699163; called by muse, mutect2, varscan2
- OBSCN | c.3648C>T p.V1216= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV52769992; called by mutect2, varscan2
- OR52E2 | c.969G>A p.T323= | Silent (SNP) | VAF 31/55 reads (56%) | catalogued as rs148031312, COSV58611715, COSV58612319; called by muse, mutect2, varscan2
- OSBPL6 | c.2421C>T p.P807= | Silent (SNP) | VAF 51/136 reads (38%) | catalogued as COSV99507224; called by muse, mutect2, varscan2
- PARD3B | c.2511G>A p.T837= (on ENST00000406610 / NM_001302769.2; = p.T768= on NM_057177.7) | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as rs750239561, COSV62510096; called by mutect2, varscan2
- PCNX2 | c.2781C>T p.A927= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV50797604; called by muse, mutect2, varscan2
- PORCN | c.828G>A p.E276= (on ENST00000326194 / NM_203475.3; = p.E265= on NM_022825.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV58226141; called by muse, mutect2, varscan2
- PSAPL1 | c.867G>A p.K289= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV59842992; called by muse, mutect2, varscan2
- PSG7 | c.453C>T p.I151= | Silent (SNP) | VAF 65/108 reads (60%) | catalogued as COSV68445009; called by muse, mutect2, varscan2
- PSG8 | c.756G>A p.R252= | Silent (SNP) | VAF 12/208 reads (6%) | catalogued as rs1266662840, COSV60609503, COSV60611303; called by muse, mutect2
- RAB27B | c.570G>A p.E190= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV50494755; called by muse, mutect2, varscan2
- RAB40B | c.519C>T p.I173= | Silent (SNP) | VAF 39/66 reads (59%) | catalogued as rs142445256; called by mutect2, varscan2
- SERPINB3 | c.819G>A p.Q273= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as COSV52191340; called by muse, mutect2, varscan2
- SIAH3 | c.762G>A p.G254= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV68551785; called by muse, mutect2, varscan2
- SLC16A14 | c.1338C>T p.I446= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs775632259, COSV54618251; called by muse, mutect2, varscan2
- SLITRK2 | c.1938C>T p.R646= | Silent (SNP) | VAF 28/128 reads (22%) | catalogued as rs1556944831, COSV59425049; called by muse, varscan2
- SPNS2 | c.375C>T p.V125= | Silent (SNP) | VAF 34/61 reads (56%) | catalogued as COSV100223579; called by muse, mutect2, varscan2
- TEPSIN | c.600C>T p.S200= | Silent (SNP) | VAF 41/58 reads (71%) | catalogued as COSV56142603; called by muse, mutect2, varscan2
- TERT | c.2328C>T p.F776= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs748248614, COSV57200474; ClinVar: likely benign; called by mutect2, varscan2
- TMEM132A | c.1713C>A p.P571= (on ENST00000453848 / NM_178031.3; = p.P572= on NM_017870.4) | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV50004872; called by mutect2, varscan2
- TMEM163 | c.486C>T p.F162= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV56106271; called by muse, mutect2, varscan2
- TMEM177 | c.171C>T p.L57= | Silent (SNP) | VAF 46/151 reads (30%) | catalogued as COSV55608607; called by muse, mutect2, varscan2
- TMEM95 | c.288C>T p.L96= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV50135552; called by muse, mutect2, varscan2
- TRIM10 | c.123C>T p.T41= | Silent (SNP) | VAF 54/143 reads (38%) | catalogued as rs767047205, COSV64989373, COSV64990078; called by muse, mutect2, varscan2
- TRIM33 | c.3265T>C p.L1089= | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as COSV61822315; called by muse, mutect2, varscan2
- TYSND1 | c.1131A>G p.E377= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as COSV54642854; called by muse, mutect2, varscan2
- VARS1 | c.1506C>T p.S502= | Silent (SNP) | VAF 189/588 reads (32%) | catalogued as rs761765858, COSV65155038; called by muse, mutect2, varscan2
- ZNF280C | c.1992C>T p.N664= | Silent (SNP) | VAF 92/305 reads (30%) | catalogued as COSV63968845; called by muse, mutect2, varscan2
- MYL3 | chr3:46832981 C>T | 3'Flank (SNP) | VAF 31/85 reads (36%) | catalogued as COSV101451260; called by muse, mutect2, varscan2
- MYL3 | chr3:46832982 C>T | 3'Flank (SNP) | VAF 31/85 reads (36%) | catalogued as COSV101451261, COSV70133759; called by muse, mutect2, varscan2
